Gene-level copy-number profile of tumor specimen TCGA-13-1819-01A from TCGA case TCGA-13-1819, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 59.2 years (21,635 days).
Specimen TCGA-13-1819-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5876f156-ec7c-496e-9b1d-97d3824a239f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1819-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6bb8ebc4-9213-4dc7-8b81-3ecbd2764851

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 19; copy number 1: 17,532; copy number 2: 30,373; copy number 3: 10,487; copy number 4: 825; copy number 5: 574; copy number 6: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-1819-01): tumor purity 0.9, ploidy 1.96, whole-genome doublings 0 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,130,021–186,130,155, 1 gene: AC104070.1.
- chr14:103,561,896–103,714,249, 1 gene (within-gene range 0–1): KLC1.
- chr14:103,562,962–103,685,924, 1 gene (within-gene range 0–1): AL139300.1.
- chr14:103,682,362–103,733,668, 8 genes: AL049840.2, AL049840.6, AL049840.3, AL049840.4, AL049840.5, XRCC3, ZFYVE21, Y_RNA.
- chr14:103,762,803–103,763,277, 1 gene: AL049840.7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 582 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:136,721,394–137,796,678, 18 genes, copy number 5: RNU6-789P, AC117382.1, AC117382.2, AC096992.3, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1, RNA5SP142, AC117440.1, NPM1P17, SOX14, LINC01210, AC007159.1.
- chr3:141,228,726–141,471,902, 8 genes, copy number 6: PXYLP1, AC022215.2, AC022215.1, AC117383.1, AC117383.2, ZBTB38, AC010184.1, KRT18P35.
- chr3:195,274,745–198,222,513, 118 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:66,964,099–67,056,604, 1 gene, copy number 5 (within-gene range 3–5): PPP1R42.
- chr8:67,043,079–69,104,242, 23 genes, copy number 5 (within-gene range 4–5): COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592.
- chr8:70,424,125–78,558,503, 110 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:118,189,455–125,091,819, 119 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:2,875,442–17,797,124, 185 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,233. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
